Somatic mutation profile of tumor specimen MP2PRT-PAUWGU-TMP1-A (aliquot MP2PRT-PAUWGU-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAUWGU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,473 days).
Specimen MP2PRT-PAUWGU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f9a5c05-f064-40a9-92fa-b32d7aa257d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUWGU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUWGU-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31c91c77-175d-4f2a-a3c8-d495078c1a78

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC099489.1 | c.2674C>T p.R892W | Missense Mutation (SNP) | VAF 69/436 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs1021699542; called by muse, mutect2, varscan2
- BPIFB4 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.878); catalogued as rs535736291, COSV64951283; called by muse, mutect2
- CD109 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs201376556, COSV54657755; called by muse, mutect2, varscan2
- CEP170 | c.4550C>T p.P1517L | Missense Mutation (SNP) | VAF 22/345 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as rs561098524; called by muse, mutect2
- FNDC7 | c.1558G>A p.V520I | Missense Mutation (SNP) | VAF 170/364 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1025509229; called by muse, mutect2, varscan2
- PCDHB1 | c.1420G>T p.V474F | Missense Mutation (SNP) | VAF 12/414 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60631775; called by muse, mutect2
- TMEM179 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 58/505 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as rs776030316; called by muse, mutect2, varscan2
- DOCK1 | c.3001A>T p.N1001Y | Missense Mutation (SNP) | VAF 231/359 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- SRP68 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 80/359 reads (22%) | called by muse, mutect2, varscan2
- TRAJ6 | c.1del p.A2Hfs*? | Frame Shift Del (DEL) | VAF 30/424 reads (7%) | called by mutect2, pindel*
- WFDC5 | c.286T>C p.C96R | Missense Mutation (SNP) | VAF 16/544 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- JMY | c.1131C>T p.T377= | Silent (SNP) | VAF 38/517 reads (7%) | catalogued as rs373711492, COSV68661465; called by muse, mutect2
- SH3BP4 | c.2598G>A p.K866= | Silent (SNP) | VAF 18/513 reads (4%) | catalogued as rs1225757771; called by muse, mutect2
